Somatic mutation profile of tumor specimen TCGA-81-5911-01A (aliquot TCGA-81-5911-01A-12D-1845-08) from TCGA case TCGA-81-5911, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 33.7 years (12,292 days).
Specimen TCGA-81-5911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98a081f8-dde1-4b00-92df-d6c6c43332cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-81-5911-10A (Blood Derived Normal), aliquot TCGA-81-5911-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6fc7704-fe43-4d46-ab9e-7d80c5ecad67

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 484/686 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 38/59 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204859, CD110173, CM983501, COSV64288670, COSV64294671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKFN1 | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100592948, COSV59453535; called by muse, mutect2, varscan2
- ATP2A3 | c.653A>T p.K218I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV59232048; called by muse, mutect2, varscan2
- CEP95 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as rs782719413, COSV73609504; called by muse, mutect2, varscan2
- CNTN6 | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs778853255, COSV63165383, COSV63177259, COSV63179266; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CWF19L2 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs146937549, COSV56516360; called by muse, mutect2, varscan2
- CYB561 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV62540024; called by muse, mutect2, varscan2
- DNAJC28 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1363635870, COSV58721942; called by muse, mutect2, varscan2
- LAIR1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs201618231, COSV57305754, COSV57307996; called by muse, mutect2, varscan2
- LILRA4 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as rs763023157, COSV52493499; called by muse, mutect2, varscan2
- NOTCH2 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.315); catalogued as rs144936899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2A2 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs374016349; called by muse, mutect2, varscan2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, mutect2, varscan2
- PLEKHM3 | c.851C>G p.T284S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV66817628; called by muse, mutect2, varscan2
- RB1 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 27/42 reads (64%) | catalogued as COSV57300514; called by muse, mutect2, varscan2
- SIGLEC1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV52458416; called by muse, mutect2, varscan2
- SLC10A6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV56722529; called by muse, mutect2, varscan2
- SOS1 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV67676511; called by muse, mutect2, varscan2
- TEX13B | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV57203272, COSV57203471; called by muse, mutect2, varscan2
- TICRR | c.3002C>A p.S1001Y | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253082479, COSV51544191; called by muse, mutect2, varscan2
- OR7G1 | c.269dup p.S91Efs*83 | Frame Shift Ins (INS) | VAF 61/290 reads (21%) | called by mutect2, pindel, varscan2
- FADS2 | c.687G>A p.K229= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs1049430775, COSV53900603; called by muse, mutect2, varscan2
- FRAS1 | c.8388C>T p.N2796= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs376748689; called by muse, mutect2, varscan2
- IL1RL2 | c.228C>T p.D76= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs769263185, COSV51817055; called by muse, mutect2, varscan2
- MUC5B | c.11220C>T p.T3740= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs761306783, COSV71594036; called by muse, mutect2, varscan2
